CCDI case PBBWBL — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Granular Cell Tumors and Alveolar Soft Part Sarcomas; Primary site: Eye and adnexa.
https://portal.gdc.cancer.gov/cases/c99bb937-6448-442d-a867-64dde0a77321

Demographics
Sex at birth: female; Race: white; Vital status: Alive.

Diagnoses (1)
1. Alveolar rhabdomyosarcoma: ICD-O-3 morphology code: 8920/3; Tissue or organ of origin: Eye, NOS; Age at diagnosis: 7.4 years (2,685 days).

Biospecimens (3 samples)
- Sample 0DIQZQ: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DIR0C: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DIR3Y: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
